Gene-level copy-number profile of tumor specimen RC-B5DD-TTP1-A from RC case RC-B5DD, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Extranodal NK/T-cell lymphoma, nasal type; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 81.4 years (29,732 days).
Specimen RC-B5DD-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e337a993-23bf-48bf-9a59-90b14ee0b557.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B5DD-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/651be3d4-c60a-4552-95f8-a383da08796f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,910; copy number 2: 53,087; copy number 3: 1,919.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,066. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
